Somatic mutation profile of tumor specimen TCGA-ER-A195-06A (aliquot TCGA-ER-A195-06A-11D-A196-08) from TCGA case TCGA-ER-A195, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.8 years (17,460 days).
Specimen TCGA-ER-A195-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a4a924-17f2-4255-b6a4-117da19d21bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A195-10A (Blood Derived Normal), aliquot TCGA-ER-A195-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c483492c-5190-4869-8d7e-cfa9f1273f8a

The open-access MAF lists 308 somatic variants for this specimen: 194 protein-altering or splice-affecting, 108 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 108, Nonsense Mutation 8, Intron 2, Splice Region 2, Translation Start Site 1, 5'Flank 1, Splice Site 1, RNA 1, Frame Shift Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA4 | c.3524G>A p.G1175E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64675791; called by muse, mutect2, varscan2
- ADAM23 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs376742781; called by muse, mutect2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADGRG4 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV54962451; called by muse, mutect2, varscan2
- ADIPOR1 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV61852086; called by muse, mutect2, varscan2
- ADNP2 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV51541068, COSV51542885; called by muse, mutect2, varscan2
- AKAP6 | c.6502G>A p.E2168K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs758568024, COSV55224117; called by muse, mutect2, varscan2
- ALS2 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs1038752763, COSV51890225; called by muse, mutect2, varscan2
- ANK3 | c.9175G>A p.E3059K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs868622451, COSV55067533; called by muse, mutect2, varscan2
- ANKS1B | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs267603734, COSV61335270; called by mutect2, varscan2
- ANO4 | c.181C>T p.L61F (on ENST00000392977 / NM_001286615.2; = p.L26F on NM_178826.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV54589191; called by muse, mutect2, varscan2
- ANPEP | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.208); catalogued as COSV55593331; called by muse, mutect2, varscan2
- ARFGEF3 | c.5210T>A p.V1737D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52464502; called by muse, mutect2, varscan2
- ARHGAP30 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as rs140780168; called by muse, mutect2, varscan2
- ARSF | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV63840401; called by muse, varscan2
- ASTN2 | c.1957C>T p.R653C (on ENST00000313400 / NM_001365069.1; = p.R602C on NM_014010.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759200691, COSV57763735, COSV57810099; called by muse, mutect2, varscan2
- BEND4 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV72469267; called by muse, varscan2
- BICRAL | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58407449; called by muse, mutect2, varscan2
- C10orf120 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV61492353; called by muse, mutect2, varscan2
- C8B | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760262006, COSV64778681; called by mutect2, varscan2
- CACNA1H | c.6359C>T p.P2120L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV52356651; called by muse, mutect2, varscan2
- CALN1 | c.258G>A p.M86I (on ENST00000329008 / NM_001017440.3; = p.M128I on NM_031468.4) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100209656; called by mutect2, varscan2
- CAMKK2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV61216469; called by muse, mutect2, varscan2
- CAP2 | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57734829; called by muse, mutect2, varscan2
- CAPN1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54200369; called by muse, mutect2, varscan2
- CD163L1 | c.445+1G>A p.X149_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV58020859; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CLCA1 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.113); catalogued as COSV52329141; called by muse, mutect2, varscan2
- CLCN5 | c.555T>A p.Y185* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV56585702; called by muse, mutect2, varscan2
- COL13A1 | c.1618G>A p.E540K (on ENST00000398978 / NM_001130103.2; = p.E483K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); catalogued as rs964502179, COSV62572480; called by muse, mutect2, varscan2
- COL18A1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV62704498; called by muse, mutect2, varscan2
- COL20A1 | c.3380G>A p.R1127K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58922895; called by muse, mutect2, varscan2
- COL25A1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67647406, COSV67654777; called by muse, mutect2, varscan2
- COL6A2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.007); catalogued as COSV56000594; called by muse, mutect2, varscan2
- DCAF4L2 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV60477184, COSV60480639; called by muse, mutect2, varscan2
- DCC | c.4072G>A p.E1358K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as COSV71437045; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- DECR1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.511); catalogued as COSV55168950; called by muse, mutect2, varscan2
- DECR1 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.609); catalogued as COSV99616611; called by muse, mutect2, varscan2
- DENND4B | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63410677; called by muse, mutect2, varscan2
- DLGAP5 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV55964475; called by muse, mutect2, varscan2
- DSC1 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV57148915, COSV99937578; called by muse, mutect2, varscan2
- DSE | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59062144, COSV59066224; called by muse, mutect2, varscan2
- ELMO2 | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.23); catalogued as COSV51684997; called by muse, varscan2
- EOMES | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs1344038707, COSV55412384, COSV55413869; called by muse, mutect2, varscan2
- FAM71B | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 132/379 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57228970; called by muse, mutect2, varscan2
- FAP | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV51859418; called by muse, mutect2, varscan2
- FCRL3 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV63843612; called by muse, mutect2, varscan2
- FCRL5 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs762961843, COSV62517656; called by muse, mutect2, varscan2
- FIBCD1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV53394706; called by muse, mutect2
- GART | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV63113566; called by muse, mutect2, varscan2
- GCN1 | c.4762C>T p.P1588S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56111837; called by muse, mutect2, varscan2
- GSTA5 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52863358; called by muse, mutect2, varscan2
- GTF2IRD1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56089464; called by mutect2, varscan2
- GUCA2B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV65368288; called by muse, mutect2, varscan2
- HEPHL1 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59894373; called by muse, mutect2, varscan2
- HLCS | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs1414043333, COSV100358654; called by muse, mutect2, varscan2
- HMCN1 | c.10753C>T p.R3585* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs748287658, COSV54921875; called by muse, mutect2, varscan2
- HYDIN | c.9904G>A p.D3302N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs773404736, COSV66881391; called by mutect2, varscan2
- IFIH1 | c.1616T>C p.F539S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV55128617; called by muse, mutect2, varscan2
- IKZF1 | c.674A>T p.N225I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100498810; called by muse, mutect2, varscan2
- INHBE | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV56988659; called by mutect2, varscan2
- INSRR | c.3032C>T p.A1011V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63875717; called by muse, mutect2, varscan2
- IP6K3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs770106533, COSV99540214; called by mutect2, varscan2
- IRGC | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54985334; called by muse, mutect2, varscan2
- KCND3 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV56185630; called by muse, mutect2, varscan2
- KCNH1 | c.2245G>A p.E749K (on ENST00000271751 / NM_172362.3; = p.E722K on NM_002238.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV55076207, COSV55093144; called by muse, mutect2, varscan2
- KCNT2 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs754243300, COSV54095777; called by muse, mutect2, varscan2
- KEL | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV62336613; called by muse, mutect2, varscan2
- KIAA1549L | c.1895C>T p.S632L (on ENST00000321505; = p.S929L on NM_012194.3) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55778026; called by muse, mutect2, varscan2
- KIR3DL1 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); catalogued as COSV58496978; called by muse, varscan2
- KLHL1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64767755, COSV64788264; called by muse, mutect2, varscan2
- KLHL5 | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775477489, COSV54671691, COSV54677154; called by muse, varscan2
- KMT5A | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV57864079, COSV57865187; called by muse, mutect2, varscan2
- KRT31 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs143943601; called by muse, mutect2, varscan2
- KRT76 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as rs776824000, COSV60121285; called by muse, mutect2, varscan2
- KRT78 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58852804; called by muse, mutect2, varscan2
- KRTAP10-11 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV58177928, COSV58178864; called by muse, mutect2, varscan2
- LAMB4 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV52725615; called by mutect2, varscan2
- LDHA | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV99908453; called by muse, mutect2, varscan2
- LEF1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54470377; called by muse, mutect2, varscan2
- LIPE | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.058); catalogued as COSV54924305; called by muse, mutect2, varscan2
- LMO2 | c.371C>T p.A124V (on ENST00000395833 / NM_001142315.2; = p.A193V on NM_005574.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV57646905; called by muse, mutect2, varscan2
- LOXL2 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66692620; called by muse, mutect2, varscan2
- LRBA | c.7577A>G p.N2526S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63960249; called by muse, mutect2, varscan2
- LRP1B | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs766749470, COSV67192207; called by muse, mutect2, varscan2
- LRRIQ3 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV63047560; called by mutect2, varscan2
- MAGEC1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs1295614131, COSV53569766; called by muse, mutect2, varscan2
- MAN2A1 | c.2677T>C p.Y893H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV54855570; called by muse, mutect2, varscan2
- MAP10 | c.2726C>T p.S909L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69364360; called by muse, mutect2, varscan2
- MEFV | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV54825180; called by muse, varscan2
- MGAT4C | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59834924; called by mutect2, varscan2
- MPHOSPH9 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs765664952, COSV56622208; called by muse, mutect2, varscan2
- MUC16 | c.27434C>T p.S9145F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as COSV101198359, COSV67462435, COSV67480710; called by muse, mutect2, varscan2
- MUC17 | c.11198C>T p.S3733L | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60296811; called by muse, mutect2, varscan2
- MUC5B | c.12560T>C p.L4187S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV71594277; called by muse, mutect2, varscan2
- MUS81 | c.1062C>T p.F354= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100337420; called by muse, varscan2
- MUSK | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs754275653, COSV51891534; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH1 | c.5734G>A p.E1912K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56844935; called by muse, mutect2, varscan2
- MYO18B | c.7501G>A p.D2501N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59142233; called by muse, varscan2
- MYO5B | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762183636, COSV53214965; called by muse, mutect2, varscan2
- MYO7B | c.557A>G p.E186G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67349771; called by muse, mutect2, varscan2
- NCOA6 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.604); catalogued as COSV100750405; called by muse, mutect2, varscan2
- NEBL | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529858, COSV101009015, COSV65802861; called by muse, mutect2, varscan2
- NEK9 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53132469; called by muse, mutect2, varscan2
- NFATC4 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51607650; called by muse, mutect2, varscan2
- NID1 | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV51625159; called by muse, mutect2, varscan2
- NLRP5 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs1421935695, COSV66765840; called by muse, mutect2
- NOS1 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs548157712, COSV57617501; called by muse, mutect2, varscan2
- NPAP1 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV61508169; called by muse, mutect2, varscan2
- NRG3 | c.1158G>A p.K386= | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as rs267602593, COSV64548620; called by muse, mutect2, varscan2
- NRP1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55172639; called by muse, mutect2, varscan2
- NUTM2A | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774012134, COSV67742064; called by muse, mutect2, varscan2
- OCLN | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV62285750; called by muse, mutect2, varscan2
- OR14A16 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV62927126; called by muse, mutect2, varscan2
- OR1A1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs778242671, COSV58404343; called by muse, mutect2, varscan2
- OR2B3 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); catalogued as rs866363855, COSV65850798; called by muse, mutect2, varscan2
- OR2L8 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs1427639545, COSV61727596; called by muse, mutect2
- OR4K1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV53460299; called by muse, mutect2, varscan2
- OR4S2 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56747700; called by muse, mutect2, varscan2
- OR5D14 | c.888T>G p.N296K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV59457527; called by muse, mutect2, varscan2
- OR5F1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV53547736; called by muse, mutect2, varscan2
- OR5W2 | c.182T>A p.F61Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.323); catalogued as COSV60617470; called by muse, mutect2, varscan2
- OR6K2 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774223413; called by mutect2, varscan2
- OR6Q1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1020473036, COSV56933068; called by muse, mutect2, varscan2
- OR8U1 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56417502; called by muse, mutect2
- OTOGL | c.2191C>T p.P731S (on ENST00000547103; = p.P722S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV72007062; called by muse, mutect2, varscan2
- P3H2 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs374266006; called by mutect2, varscan2
- PALMD | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as rs540907116, COSV54165867; called by muse, mutect2, varscan2
- PARD3B | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62521554; called by muse, mutect2, varscan2
- PCDH12 | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99191581; called by muse, mutect2
- PCDH15 | c.5804G>A p.G1935E | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1264005664, COSV57269638; called by muse, mutect2, varscan2
- PER3 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs145870917; called by muse, mutect2, varscan2
- PIGU | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV54164825; called by muse, mutect2, varscan2
- PLCD3 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59561839; called by muse, mutect2, varscan2
- PLCZ1 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56856499; called by muse, mutect2, varscan2
- POT1 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62932761; called by muse, mutect2, varscan2
- PRDM9 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57010382; called by muse, mutect2, varscan2
- PRKCH | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60650649; called by muse, varscan2
- PRUNE2 | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as COSV65044587; called by muse, mutect2, varscan2
- PSD3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs755138989, COSV58974595; called by muse, mutect2, varscan2
- PTPRD | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV61936192, COSV61975980; called by muse, mutect2, varscan2
- RAD23B | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63659727; called by muse, mutect2, varscan2
- RBM48 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV56003290; called by muse, mutect2, varscan2
- REXO4 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64242049; called by muse, mutect2, varscan2
- SCN2A | c.3460G>A p.G1154R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as COSV51849513; called by muse, mutect2, varscan2
- SCN3A | c.4528C>T p.R1510C | Missense Mutation (SNP) | VAF 75/302 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs758596091, COSV51806986; called by muse, mutect2, varscan2
- SELE | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60976870; called by muse, mutect2, varscan2
- SERPINB3 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52193036; called by muse, mutect2, varscan2
- SERPINB6 | c.526C>T p.P176S (on ENST00000612421 / NM_001271823.2; = p.P157S on NM_004568.6) | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59566508; called by muse, mutect2, varscan2
- SFSWAP | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1272454105, COSV55526774; called by muse, mutect2, varscan2
- SGCZ | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs879244879, COSV66029798; called by muse, mutect2, varscan2
- SHISAL1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs772497929, COSV66987863; called by muse, mutect2, varscan2
- SLC16A9 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs752279993, COSV68099884; called by muse, mutect2, varscan2
- SLC35F3 | c.298C>T p.L100F (on ENST00000366617 / NM_001300845.1; = p.L169F on NM_173508.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1166930825, COSV64020771; called by muse, mutect2, varscan2
- SLC7A13 | c.1382A>T p.N461I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99879257; called by muse, mutect2, varscan2
- SLC8A1 | c.1369T>A p.Y457N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247552; called by muse, mutect2, varscan2
- SLC8A1 | c.1368T>A p.D456E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247555; called by muse, mutect2, varscan2
- SOAT2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV56857727; called by muse, mutect2, varscan2
- SORL1 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148966249; called by muse, mutect2, varscan2
- SPINT1 | c.1108G>A p.E370K (on ENST00000344051 / NM_181642.3; = p.E354K on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV59802795; called by muse, mutect2, varscan2
- SYCE1 | c.694C>T p.R232C (on ENST00000343131 / NM_001143764.3; = p.R196C on NM_130784.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs566597399, COSV58218434; called by muse, mutect2, varscan2
- SYTL4 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV52169822; called by mutect2, varscan2
- TACR3 | c.324G>A p.W108* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV59205550; called by muse, mutect2, varscan2
- TAP2 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100886962; called by muse, mutect2, varscan2
- TAP2 | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100886964; called by mutect2, varscan2
- TENM3 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs749703754, COSV69305365; called by mutect2, varscan2
- THSD4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as rs1387849216, COSV55977765; called by muse, mutect2, varscan2
- TIE1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758194663, COSV65250549; called by muse, mutect2, varscan2
- TLN2 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV60887508, COSV60892653; called by muse, mutect2, varscan2
- TLR4 | c.808G>A p.E270K (on ENST00000355622 / NM_138554.5; = p.E230K on NM_003266.4) | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1564265693, COSV62923835; called by muse, mutect2, varscan2
- TLR9 | c.2953C>T p.Q985* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV62347745; called by muse, mutect2, varscan2
- TMEFF2 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55832368, COSV55836960; called by muse, mutect2, varscan2
- TMEM132B | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54755080; called by mutect2, varscan2
- TRAV12-1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as rs1327234857; called by muse, mutect2, varscan2
- TVP23A | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51594776; called by muse, mutect2, varscan2
- UBL7 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs750604696, COSV63706053; called by muse, mutect2, varscan2
- UGT2A1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54139153; called by muse, mutect2, varscan2
- VSIR | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as rs370867717; called by mutect2, varscan2
- WDR59 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50939760; called by muse, mutect2, varscan2
- XIRP1 | c.4787C>T p.P1596L | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1245088781, COSV61139942; called by muse, mutect2, varscan2
- XIRP2 | c.10052G>A p.G3351E (on ENST00000628543; = p.G3526E on NM_152381.6) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1473025678, COSV54693324; called by muse, mutect2, varscan2
- ZAP70 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV53855892; called by muse, mutect2, varscan2
- ZDHHC19 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56349497; called by mutect2, varscan2
- ZFP91 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60160456; called by muse, mutect2, varscan2
- ZNF208 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV68105273; called by muse, varscan2
- ZNF347 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61969972, COSV61970543; called by muse, mutect2, varscan2
- ZNF479 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV58637660, COSV58641431; called by muse, varscan2
- ZNF485 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV62424964; called by muse, mutect2, varscan2
- ZNF777 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV56099173; called by mutect2, varscan2
- ZNF816 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.208); catalogued as COSV54411898; called by muse, mutect2, varscan2
- IGKV1-5 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- POLR3E | c.1134_1141del p.C378* | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- AAAS | c.394C>T p.L132= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV52933731; called by muse, mutect2, varscan2
- ABCA12 | c.7272G>A p.S2424= (on ENST00000272895 / NM_173076.3; = p.S2106= on NM_015657.3) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs150309991; called by mutect2, varscan2
- ACD | c.153C>T p.L51= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1207134820, COSV54665585, COSV54667112, COSV54669526; called by mutect2, varscan2
- ADGRB3 | c.4356G>A p.R1452= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1478638766, COSV53253899; called by muse, mutect2, varscan2
- ADGRE1 | c.186C>T p.F62= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV51678664; called by muse, mutect2, varscan2
- AMBP | c.528G>A p.E176= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV54324810; called by muse, mutect2, varscan2
- ANKRD30A | c.3774G>A p.R1258= (on ENST00000611781; = p.R1202= on NM_052997.2) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV64606841; called by muse, mutect2, varscan2
- ANKS1A | c.1323G>A p.R441= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV64462704; called by muse, mutect2, varscan2
- BCAS3 | c.651C>T p.F217= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1245928798, COSV66778375; called by muse, mutect2, varscan2
- BDKRB2 | c.177C>T p.I59= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs1331787044, COSV60016068; called by muse, mutect2, varscan2
- BDNF | c.123G>A p.G41= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV59236910; called by muse, mutect2, varscan2
- BRINP1 | c.1881C>T p.T627= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV56307309; called by muse, varscan2
- BRPF1 | c.972C>T p.P324= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs762593544, COSV57406645, COSV57408864; called by muse, mutect2, varscan2
- BSN | c.8910G>A p.K2970= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs773069345, COSV56523566; called by muse, varscan2
- CACNA1H | c.1092C>T p.I364= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs370787853; called by mutect2, varscan2
- CATSPER1 | c.540C>T p.L180= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs369936891; called by muse, mutect2, varscan2
- CCDC151 | c.450G>A p.L150= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV62698631; called by muse, mutect2, varscan2
- CD300LG | c.309G>A p.G103= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs889140352, COSV53224998; called by muse, mutect2, varscan2
- CFAP43 | c.1398C>T p.V466= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs763217980, COSV53379793; called by mutect2, varscan2
- CLIP2 | c.1401C>T p.H467= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs558749004, COSV99792447; called by mutect2, varscan2
- CNTNAP5 | c.2685G>A p.R895= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV70499611; called by muse, mutect2, varscan2
- COBL | c.1323C>T p.D441= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54352427; called by muse, varscan2
- CSMD3 | c.822G>A p.E274= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV52255656; called by muse, mutect2, varscan2
- CTDSPL | c.462C>T p.F154= (on ENST00000273179 / NM_001008392.2; = p.F143= on NM_005808.3) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56203446; called by muse, mutect2, varscan2
- CWC25 | c.1197C>T p.S399= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- DENND1A | c.960C>T p.F320= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs373730181; called by mutect2, varscan2
- DHX16 | c.1539T>C p.S513= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64564874; called by muse, mutect2, varscan2
- DISP3 | c.3792G>A p.E1264= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV53821213; called by muse, mutect2, varscan2
- DMBX1 | c.429G>A p.E143= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs758855440, COSV63602360; called by muse, mutect2, varscan2
- DNAH1 | c.7842G>A p.K2614= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV70232780; called by muse, mutect2, varscan2
- DNAJC11 | c.1272G>A p.R424= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV50011349; called by muse, mutect2
- DYSF | c.4464G>A p.R1488= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV50498186; called by muse, mutect2
- EGFLAM | c.2361C>T p.P787= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100380853; called by muse, mutect2, varscan2
- FAT1 | c.1446C>T p.V482= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV71675243; called by muse, mutect2, varscan2
- FOXP1 | c.639C>T p.A213= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV59548643; called by muse, mutect2, varscan2
- FREM1 | c.1089C>T p.L363= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV63087474; called by muse, mutect2, varscan2
- FYB1 | c.1026G>A p.P342= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs776689421, COSV60945409; called by muse, mutect2, varscan2
- GABRA5 | c.816G>A p.V272= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV59483263; called by muse, mutect2, varscan2
- GALNT13 | c.609C>T p.V203= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs966226903, COSV67230945; called by mutect2, varscan2
- GLRA2 | c.600G>A p.L200= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV54341600, COSV54344917; called by muse, mutect2, varscan2
- GTF2IRD1 | c.801C>T p.I267= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV56089471; called by muse, mutect2, varscan2
- HRH3 | c.153C>G p.G51= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58049529; called by muse, mutect2
- HRNR | c.1920C>T p.G640= | Silent (SNP) | VAF 54/238 reads (23%) | catalogued as rs569965567, COSV64258011; called by muse, varscan2
- HTR3E | c.213G>A p.A71= (on ENST00000415389 / NM_001256613.1; = p.A86= on NM_182589.2) | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs865810148, COSV58947948, COSV58948840; called by muse, mutect2, varscan2
- IKZF1 | c.675C>T p.N225= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100498811; called by muse, mutect2, varscan2
- IP6K3 | c.888G>A p.R296= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99539748, COSV99540216; called by muse, mutect2, varscan2
- ITGAX | c.1374C>T p.F458= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs768257645, COSV51648875; called by muse, mutect2, varscan2
- IZUMO1 | c.963C>T p.F321= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55806887; called by mutect2, varscan2
- JRKL | c.1167C>T p.L389= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs533002391, COSV53594602; called by muse, mutect2, varscan2
- JUP | c.1356G>A p.T452= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs555082435, COSV60277189; called by muse, mutect2, varscan2
- KCNB2 | c.1899C>T p.F633= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs1257842115, COSV73050382; called by muse, mutect2, varscan2
- KCNK1 | c.819G>A p.L273= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1433931586, COSV64034835; called by muse, mutect2, varscan2
- KCTD8 | c.1335G>A p.Q445= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV63593024; called by muse, mutect2, varscan2
- KDM7A | c.1035C>T p.T345= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1176392054, COSV50093666; called by muse, mutect2, varscan2
- KIAA0319L | c.3111C>T p.T1037= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV57848330; called by muse, mutect2, varscan2
- KIF19 | c.474C>T p.I158= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV63430118; called by muse, mutect2, varscan2
- KRT31 | c.1068C>T p.Y356= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV52434271; called by muse, mutect2, varscan2
- KRT8 | c.420C>T p.F140= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs760415405, COSV53177351, COSV99510036; called by muse, mutect2, varscan2
- KSR2 | c.2175C>T p.F725= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs887069309, COSV56672676; called by mutect2, varscan2
- LANCL2 | c.765C>T p.H255= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV54651011; called by muse, mutect2, varscan2
- MARCHF1 | c.603G>A p.L201= (on ENST00000274056; = p.L184= on NM_017923.4) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56824305; called by muse, mutect2, varscan2
- MRGPRX3 | c.777C>T p.F259= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV66933493; called by muse, mutect2, varscan2
- MTARC2 | c.769C>T p.L257= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV63766097; called by muse, mutect2, varscan2
- MUSK | c.153G>A p.V51= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV51891515; called by muse, mutect2, varscan2
- MYCBPAP | c.1194C>T p.G398= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV60409907; called by muse, mutect2, varscan2
- MYH2 | c.4740G>A p.R1580= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV55431125; called by muse, mutect2, varscan2
- NCEH1 | c.775T>C p.L259= (on ENST00000538775; = p.L219= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV56436403; called by muse, mutect2, varscan2
- NCOA6 | c.2487C>G p.V829= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100750343, COSV100750406; called by muse, mutect2, varscan2
- NLGN2 | c.1101C>T p.L367= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV57211187; called by muse, mutect2, varscan2
- NOX4 | c.312C>T p.F104= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54459589; called by muse, mutect2, varscan2
- NUP155 | c.3852C>T p.F1284= (on ENST00000231498 / NM_153485.3; = p.F1225= on NM_004298.4) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs768396938, COSV51526245; called by muse, mutect2, varscan2
- NYAP1 | c.735C>T p.T245= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV55720647; called by muse, mutect2, varscan2
- OR1J2 | c.897G>A p.E299= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV58944846; called by muse, mutect2, varscan2
- OR1L4 | c.522C>T p.I174= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV52341070; called by muse, mutect2, varscan2
- OR4N2 | c.264G>A p.A88= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs144051874; called by muse, mutect2, varscan2
- OR4Q3 | c.282C>T p.F94= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV59177427; called by muse, mutect2, varscan2
- OR5AS1 | c.891G>A p.V297= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1565026622, COSV57982068; called by muse, mutect2, varscan2
- OR5F1 | c.294C>T p.F98= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV53545361, COSV99558748; called by muse, mutect2, varscan2
- OR6C1 | c.938G>A p.*313= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV101110569, COSV65572992; called by muse, mutect2, varscan2
- PAQR3 | c.768C>G p.S256= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV55010937; called by muse, mutect2, varscan2
- PCDHGA2 | c.132C>T p.F44= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV53988638; called by muse, mutect2, varscan2
- PCLO | c.10404G>A p.V3468= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs774405078, COSV61652309; called by muse, mutect2, varscan2
- PCLO | c.1479G>A p.Q493= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as COSV61652324; called by muse, mutect2, varscan2
- PDE3B | c.1224C>T p.Y408= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as rs1440158082, COSV56387559; called by muse, mutect2, varscan2
- PDZD8 | c.1302C>T p.I434= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100559664; called by muse, mutect2, varscan2
- PFKFB1 | c.429C>T p.I143= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as rs758645656, COSV66628964; called by muse, mutect2, varscan2
- PKD2L1 | c.1563C>T p.L521= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs753613040, COSV58397647; called by muse, mutect2, varscan2
- PLEC | c.8955C>T p.D2985= (on ENST00000322810 / NM_201380.4; = p.D2875= on NM_000445.5) | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs1035066766, COSV59667753; ClinVar: likely benign; called by mutect2, varscan2
- PPP1R16B | c.1245C>T p.I415= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV55381174; called by muse, mutect2, varscan2
- PTPN9 | c.750C>T p.F250= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV60722401; called by muse, mutect2, varscan2
- PTPRN2 | c.1449G>A p.E483= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV67052013; called by muse, mutect2, varscan2
- SAMD9L | c.3168C>T p.S1056= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV59083610; called by muse, mutect2, varscan2
- SARDH | c.2295C>T p.Y765= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV64100470; called by mutect2, varscan2
- SCN3B | c.453G>A p.E151= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54800432; called by muse, mutect2, varscan2
- SEC16A | c.1473C>T p.P491= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV51534987; called by muse, varscan2
- SFSWAP | c.1149C>T p.P383= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV55526763; called by muse, mutect2, varscan2
- SLC4A8 | c.2889C>T p.L963= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs141954048, COSV60655810; called by muse, mutect2, varscan2
- SLITRK3 | c.828G>A p.R276= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs747494534, COSV53851182; called by muse, varscan2
- SPAG6 | c.1215G>A p.K405= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100510548, COSV57618584; called by muse, mutect2, varscan2
- TBC1D8B | c.2172T>G p.V724= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV52181455; called by muse, mutect2, varscan2
- TLN2 | c.6540G>A p.T2180= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs760232975, COSV60892663; called by mutect2, varscan2
- TMEM169 | c.784C>T p.L262= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV55266043; called by muse, mutect2, varscan2
- TRIML2 | c.1236C>T p.I412= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV58718160; called by muse, mutect2, varscan2
- TRPC4AP | c.1860C>T p.S620= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs776032740, COSV52681049, COSV52682471; called by muse, varscan2
- TTN | c.25137C>T p.F8379= (on ENST00000591111; = p.F7452= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/184 reads (23%) | catalogued as COSV60214131; called by muse, mutect2, varscan2
- UNC79 | c.633G>A p.R211= (on ENST00000393151 / NM_001346218.2; = p.R34= on NM_020818.5) | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs767810504, COSV56400351; called by muse, mutect2, varscan2
- WNK4 | c.249C>T p.P83= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1169347836, COSV53821560; called by muse, mutect2, varscan2
- ZNF135 | c.1461C>T p.I487= (on ENST00000313434 / NM_001289401.2; = p.I499= on NM_003436.4) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV57884286; called by muse, mutect2, varscan2
- ILF3 | c.*221C>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as rs1321505506, COSV51564823; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85626G>A | Intron (SNP) | VAF 20/91 reads (22%) | catalogued as rs758712018, COSV72280978; called by muse, mutect2, varscan2
- MFRP | chr11:119344382 C>T | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- MGAM | c.4618+10762T>C | Intron (SNP) | VAF 38/104 reads (37%) | catalogued as rs1451025432, COSV101527779; called by muse, varscan2
- MIR154 | n.23C>T | RNA (SNP) | VAF 30/119 reads (25%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676969 G>A | 3'Flank (SNP) | VAF 4/19 reads (21%) | catalogued as rs1388768465; called by muse, mutect2, varscan2
